Somatic mutation profile of tumor specimen 0DIMX8 from CCDI case PBBRLS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma in situ, NOS; Tissue or organ of origin: Larynx, NOS; Age at diagnosis: 24.4 years (8,910 days).
Specimen 0DIMX8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bfcf906-0011-421f-8dcd-651c03e6ef75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710a5868-c4e1-4689-99b2-093a32e2e2b6

The open-access MAF lists 138 somatic variants for this specimen: 114 protein-altering or splice-affecting, 7 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Intron 11, Silent 7, 3'UTR 3, Splice Site 3, Splice Region 2, 5'UTR 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.4114G>C p.D1372H | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.25); catalogued as rs535864522; called by muse, mutect2
- ARHGAP4 | c.2805C>A p.H935Q | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.986); catalogued as COSV61685867; called by muse, mutect2
- ASPSCR1 | c.1524C>A p.D508E | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as COSV100142398; called by muse, mutect2
- BBS12 | c.1514C>G p.T505S | Missense Mutation (SNP) | VAF 59/640 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.622); catalogued as rs956879119, COSV100044816; called by muse, mutect2
- CDKN2AIP | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 44/844 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs916305105, COSV56627014; called by muse, mutect2
- CEP112 | c.1787C>G p.A596G | Missense Mutation (SNP) | VAF 32/520 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67141665; called by muse, mutect2
- CIT | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.343); catalogued as COSV55865594; called by muse, mutect2
- CPT1C | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV54923298; called by muse, mutect2
- DHX9 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 26/556 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100841270; called by muse, mutect2
- DSTYK | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs1011466766, COSV65687720; called by muse, mutect2
- EML4 | c.533C>G p.A178G | Missense Mutation (SNP) | VAF 22/637 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.263); catalogued as COSV59296972; called by muse, mutect2
- EPHB6 | c.1978C>G p.R660G | Missense Mutation (SNP) | VAF 29/550 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV63893016; called by muse, mutect2
- FGF18 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51126810; called by muse, mutect2
- IPO13 | c.960C>T p.S320= | Splice Region (SNP) | VAF 32/442 reads (7%) | catalogued as rs754766963; called by muse, mutect2
- LRRCC1 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 42/756 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1233577834; called by muse, mutect2
- NF1 | c.7304G>C p.S2435T (on ENST00000358273 / NM_001042492.3; = p.S2414T on NM_000267.3) | Missense Mutation (SNP) | VAF 34/608 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.971); catalogued as COSV62205297; called by muse, mutect2
- PDE4B | c.509C>G p.A170G | Missense Mutation (SNP) | VAF 47/552 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV58481408; called by muse, mutect2
- PSMD3 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 17/501 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52857794, COSV52859346; called by muse, mutect2
- SETD5 | c.1043G>C p.R348P | Missense Mutation (SNP) | VAF 51/694 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100200590; called by muse, mutect2
- SLC22A2 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100870985; called by muse, mutect2
- TPT1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 42/652 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV58538840; called by muse, mutect2
- TRAK1 | c.302G>C p.R101T (on ENST00000327628 / NM_001349247.2; = p.R43T on NM_014965.5) | Missense Mutation (SNP) | VAF 21/648 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58266658; called by muse, mutect2
- TTC6 | c.1175A>G p.Y392C (on ENST00000267368; = p.Y1758C on NM_001310135.3) | Missense Mutation (SNP) | VAF 23/489 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs897187229; called by muse, mutect2
- UBAP1 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 34/730 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV52660246; called by muse, mutect2
- WDR17 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 47/682 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV54569151; called by muse, mutect2
- AAK1 | c.1099C>A p.R367S | Missense Mutation (SNP) | VAF 13/426 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2
- ABCA2 | c.40C>G p.R14G | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC8 | c.2291+2T>A p.X764_splice | Splice Site (SNP) | VAF 15/224 reads (7%) | called by muse, mutect2
- ACAD8 | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2
- ACTL6B | c.364G>C p.A122P | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.083); called by muse, mutect2
- AGAP2 | c.2964G>C p.L988F (on ENST00000547588 / NM_001122772.2; = p.L632F on NM_014770.4) | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKRD13A | c.1419C>G p.D473E | Missense Mutation (SNP) | VAF 138/587 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASTN1 | c.21C>G p.C7W | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- ATF1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 21/367 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- ATP6AP2 | c.823A>G p.R275G | Missense Mutation (SNP) | VAF 98/434 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATPAF2 | c.438G>C p.E146D | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.069); called by muse, mutect2
- B2M | c.346+7C>G | Splice Region (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- B9D2 | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 20/333 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BCL7C | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); called by muse, mutect2
- BDNF | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 21/440 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- BRSK2 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- C1orf158 | c.45C>G p.S15R | Missense Mutation (SNP) | VAF 55/812 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2
- CAST | c.1196C>G p.A399G (on ENST00000341926; = p.A482G on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/397 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2
- CCDC191 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 48/648 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CDHR5 | c.1696C>G p.Q566E (on ENST00000358353 / NM_001171968.2; = p.Q572E on NM_021924.5) | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.225); called by muse, mutect2
- CENPF | c.2002C>G p.L668V | Missense Mutation (SNP) | VAF 29/780 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2
- CFAP20DC | c.697C>G p.L233V (on ENST00000482387 / NM_001351530.2; = p.L108V on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/576 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.09); called by muse, mutect2
- CHD4 | c.5503G>C p.A1835P (on ENST00000357008 / NM_001363606.2; = p.A1846P on NM_001273.5) | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- CLK3 | c.932G>T p.G311V (on ENST00000395066 / NM_001130028.1; = p.G163V on NM_003992.4) | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPSF3 | c.1234C>G p.P412A | Missense Mutation (SNP) | VAF 18/555 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2
- CTCFL | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- DAGLB | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- DCAF11 | c.972C>G p.F324L | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.334); called by muse, mutect2
- DDX3X | c.939A>T p.E313D (on ENST00000399959; = p.E314D on NM_001356.5) | Missense Mutation (SNP) | VAF 58/852 reads (7%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.977); called by muse, mutect2
- DIP2B | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 19/363 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2
- DMD | c.3685C>T p.P1229S | Missense Mutation (SNP) | VAF 56/610 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2
- DNAJB13 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 34/373 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- DYNC1I1 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ENAM | c.1935G>T p.Q645H | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- EXOC7 | c.1930-1G>C p.X644_splice (on ENST00000335146 / NM_001145297.4; = p.X562_splice on NM_015219.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 23/385 reads (6%) | called by muse, mutect2
- FAM170B | c.380C>G p.A127G | Missense Mutation (SNP) | VAF 16/369 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.121); called by muse, mutect2
- FAM90A1 | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 25/547 reads (5%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.934); called by muse, mutect2
- FKBP5 | c.1098G>C p.E366D | Missense Mutation (SNP) | VAF 31/531 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- FNIP1 | c.2390C>G p.T797S | Missense Mutation (SNP) | VAF 44/501 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- HMGN2 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 34/888 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- IL1B | c.371G>C p.C124S | Missense Mutation (SNP) | VAF 49/527 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2
- IQCC | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 34/584 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.051); called by muse, mutect2
- ITPR3 | c.5158G>C p.A1720P | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- KHDC1 | c.349C>G p.L117V (on ENST00000370384 / NM_001251874.2; = p.L44V on NM_030568.5) | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- LUC7L | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.19); called by muse, mutect2
- MCC | c.2373G>T p.E791D | Missense Mutation (SNP) | VAF 22/554 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- MED25 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2
- MIER3 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 23/674 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- MPST | c.235G>C p.A79P (on ENST00000341116 / NM_001369904.2; = p.A99P on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2
- NACC2 | c.1290G>C p.E430D | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCAPH2 | c.1338G>C p.E446D | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2
- NEK1 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- NFATC4 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOL9 | c.89G>C p.S30T | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); called by muse, mutect2
- NUP214 | c.4226C>G p.A1409G | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- OPRD1 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2
- P4HA3 | c.1035G>C p.E345D | Missense Mutation (SNP) | VAF 16/495 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- PCYT1A | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 36/767 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- PLXNA3 | c.1226A>C p.D409A | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.641); called by muse, mutect2
- PLXNB1 | c.4948G>T p.E1650* | Nonsense Mutation (SNP) | VAF 20/328 reads (6%) | called by muse, mutect2
- PNMA8B | c.1631G>C p.G544A | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- POM121 | c.861-1G>C p.X287_splice (on ENST00000434423; = p.X22_splice on NM_172020.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 17/519 reads (3%) | called by muse, mutect2
- PRR14L | c.3431A>G p.E1144G | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); called by muse, mutect2
- PTPN3 | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RARA | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); called by muse, mutect2
- RGS12 | c.2282A>C p.E761A | Missense Mutation (SNP) | VAF 36/736 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- RPUSD2 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2
- RYR1 | c.7471T>A p.S2491T | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.21); called by muse, mutect2
- SFT2D2 | c.44A>C p.D15A | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2
- SMPD3 | c.1501C>G p.L501V | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.123); called by muse, mutect2
- SPTAN1 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 43/725 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2
- ST18 | c.1243C>G p.P415A | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STX7 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.145); called by muse, mutect2
- SUCO | c.3631G>C p.D1211H | Missense Mutation (SNP) | VAF 24/684 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SYNPO | c.1369G>C p.A457P (on ENST00000394243 / NM_001166208.2; = p.A213P on NM_007286.6) | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2
- SYT11 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- TDRD10 | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 14/379 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TDRD6 | c.3871C>G p.L1291V | Missense Mutation (SNP) | VAF 19/572 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.367); called by muse, mutect2
- TECPR2 | c.2221G>C p.E741Q | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.368); called by muse, mutect2
- TESK1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.574); called by muse, mutect2
- TMEM207 | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 32/834 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2
- TOMM22 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 27/748 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- TRERF1 | c.1748T>A p.V583D | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- UPF2 | c.1785G>C p.M595I | Missense Mutation (SNP) | VAF 22/720 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2
- USP32 | c.3592G>A p.D1198N | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- XYLT2 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZBTB7C | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 14/355 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZNF229 | c.1397G>T p.C466F | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2
- ZXDA | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CAMKK2 | c.387A>C p.S129= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- CCDC15 | c.342C>G p.G114= | Silent (SNP) | VAF 44/688 reads (6%) | called by muse, mutect2
- EEPD1 | c.1356G>C p.G452= | Silent (SNP) | VAF 18/492 reads (4%) | catalogued as COSV99631972; called by muse, mutect2
- IL18R1 | c.1011C>A p.I337= | Silent (SNP) | VAF 50/710 reads (7%) | catalogued as COSV52122622; called by muse, mutect2
- ITPR3 | c.432G>A p.E144= | Silent (SNP) | VAF 30/340 reads (9%) | called by muse, mutect2
- TRMT9B | c.465C>T p.D155= | Silent (SNP) | VAF 69/340 reads (20%) | catalogued as rs748847588, COSV101501632, COSV71600863; called by muse, mutect2, varscan2
- VPS18 | c.2574C>T p.F858= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- AMT | c.472-20C>G | Intron (SNP) | VAF 24/394 reads (6%) | called by muse, mutect2
- C11orf80 | chr11:66843387 G>C | 3'Flank (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- DDX41 | c.*438+29C>G | Intron (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- EIF2AK4 | c.-55C>G | 5'UTR (SNP) | VAF 4/37 reads (11%) | catalogued as rs1471013550; called by mutect2, varscan2
- FAM186B | c.96+27C>G | Intron (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2, varscan2
- FAM229A | c.134+24G>C | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- KLC4 | c.*22C>G | 3'UTR (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- MIEN1 | c.90-26C>G | Intron (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- NSMCE2 | c.*26C>A | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- ODF3B | c.-25G>C | 5'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- PFKP | c.265-370C>G | Intron (SNP) | VAF 14/298 reads (5%) | called by muse, mutect2
- RTN2 | c.1242-24C>G | Intron (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- SEPTIN1 | c.236-41C>G | Intron (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- SGF29 | c.289+84G>A | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- SLC2A1 | c.516+41C>G | Intron (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- TNFRSF4 | c.268+65C>A | Intron (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- UBAP1 | c.*23G>C | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
